Somatic mutation profile of tumor specimen TCGA-DJ-A2PZ-01A (aliquot TCGA-DJ-A2PZ-01A-21D-A18F-08) from TCGA case TCGA-DJ-A2PZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 63.9 years (23,332 days).
Specimen TCGA-DJ-A2PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b8f9665-b2b3-41fb-a3fa-9d095faa2cac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PZ-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PZ-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7fc6aa4-b015-4e2a-a400-60da1d9eb69c

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDK13 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as rs200341630, COSV51696109; called by muse, mutect2, varscan2
- DNAJB11 | c.532A>G p.T178A | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV54001759; called by muse, mutect2, varscan2
- F7 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.514); catalogued as rs751119841, COSV60644830; called by muse, mutect2, varscan2
- FCGBP | c.10960C>T p.R3654C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs1336782101; called by muse, mutect2, varscan2
- GUCA2B | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV65367859; called by muse, mutect2, varscan2
- H2AC20 | c.186del p.I63Sfs*32 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | catalogued as COSV58611535, COSV58612306; called by mutect2, pindel, varscan2
- HBS1L | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV63199942; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.794A>G p.N265S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs371219782; called by muse, mutect2, varscan2
- HSPH1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV60709999; called by muse, mutect2, varscan2
- NCOA3 | c.1073A>G p.N358S | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV59065230; called by muse, mutect2, varscan2
- STT3A | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV67064042; called by muse, mutect2, varscan2
- RBBP6 | c.3010_3011insCA p.K1004Tfs*33 | Frame Shift Ins (INS) | VAF 37/109 reads (34%) | called by mutect2, pindel, varscan2
- ANKS1A | c.1560C>T p.L520= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs867595491, COSV64458623; called by muse, mutect2, varscan2
- CAPNS1 | c.690C>A p.I230= | Silent (SNP) | VAF 98/246 reads (40%) | catalogued as COSV53084195; called by muse, mutect2, varscan2
- SYT11 | c.672C>T p.D224= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs751883423, COSV64173634; called by muse, mutect2, varscan2
